Somatic mutation profile of tumor specimen MMRF_1816_1_BM_CD138pos (aliquot MMRF_1816_1_BM_CD138pos_T1_KBS5U_L06446) from MMRF case MMRF_1816, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.9 years (24,443 days).
Specimen MMRF_1816_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac7f6671-6048-469a-9ced-48e19f077114.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1816_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1816_1_PB_Whole_C2_KBS5U_L06496; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eebdd024-a674-4d2c-8817-46770844f8f3

The open-access MAF lists 145 somatic variants for this specimen: 52 protein-altering or splice-affecting, 15 silent, 78 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, 3'UTR 36, Intron 21, Silent 15, 5'UTR 10, RNA 5, 5'Flank 5, Nonsense Mutation 2, Frame Shift Del 2, 3'Flank 1, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DEPDC5 | c.2339G>T p.R780I (on ENST00000400246; = p.R849I on NM_014662.5) | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56697813; called by muse, mutect2, varscan2
- DHX37 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1380202342; called by muse, mutect2, varscan2
- DPP4 | c.1840T>C p.S614P | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.694); catalogued as rs748191251; called by muse, mutect2
- DQX1 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs376450262, COSV101099221; called by muse, mutect2, varscan2
- FAM13A | c.1726+1G>T p.X576_splice | Splice Site (SNP) | VAF 28/65 reads (43%) | catalogued as COSV52011809; called by muse, mutect2, varscan2
- FAT4 | c.9946G>T p.G3316C | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776046433; called by muse, mutect2, varscan2
- H1-4 | c.243G>C p.K81N | Missense Mutation (SNP) | VAF 75/118 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as rs200686576, COSV56800958; called by muse, mutect2, varscan2
- IDE | c.357G>T p.K119N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as COSV99793669; called by muse, mutect2, varscan2
- OASL | c.1157C>A p.T386N | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV56567192; called by muse, mutect2, varscan2
- RBMXL3 | c.1711G>A p.A571T | Missense Mutation (SNP) | VAF 77/151 reads (51%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.057); catalogued as rs1233165705; called by muse, mutect2, varscan2
- ROGDI | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 37/46 reads (80%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); catalogued as rs1360724721; called by muse, mutect2, varscan2
- RUFY4 | c.1017G>C p.W339C | Missense Mutation (SNP) | VAF 64/108 reads (59%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV60246514; called by muse, mutect2, varscan2
- SEMA6D | c.143C>A p.P48H | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.94); catalogued as COSV100317204; called by muse, mutect2, varscan2
- SGSM1 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 56/107 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759798513, COSV101240639; called by muse, mutect2, varscan2
- TNS3 | c.2711G>A p.G904E | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs748841837; called by muse, mutect2, varscan2
- ACE2 | c.773del p.P258Qfs*24 | Frame Shift Del (DEL) | VAF 52/56 reads (93%) | called by mutect2, varscan2
- ADGRE2 | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ADGRV1 | c.1516T>C p.F506L | Missense Mutation (SNP) | VAF 27/30 reads (90%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- BEND6 | c.719C>G p.T240R | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BRI3BP | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CFAP46 | c.2324G>T p.G775V | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- CSMD3 | c.4229G>A p.C1410Y (on ENST00000297405 / NM_001363185.1; = p.C1306Y on NM_052900.3) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CYP2A6 | c.1161+8C>A | Splice Region (SNP) | VAF 37/120 reads (31%) | called by muse, mutect2, varscan2
- DLGAP2 | c.2394G>T p.Q798H | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DNAH3 | c.6224C>G p.P2075R | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EIF3B | c.1095C>A p.F365L | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- EYA1 | c.223A>T p.S75C | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); called by muse, mutect2
- F5 | c.3283G>T p.A1095S | Missense Mutation (SNP) | VAF 56/227 reads (25%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GNPTAB | c.1372A>G p.N458D | Missense Mutation (SNP) | VAF 5/148 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2
- H2AC16 | c.301G>C p.V101L | Missense Mutation (SNP) | VAF 87/153 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- KDR | c.3142G>T p.G1048C | Missense Mutation (SNP) | VAF 4/77 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LIG3 | c.113G>C p.W38S | Missense Mutation (SNP) | VAF 80/189 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- LYPD5 | c.701T>C p.L234P (on ENST00000377950 / NM_001031749.3; = p.L191P on NM_182573.2) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- MROH5 | c.3581C>A p.A1194D | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- MYZAP | c.1142T>A p.L381* | Nonsense Mutation (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- PPP1CC | c.761G>C p.G254A | Missense Mutation (SNP) | VAF 144/301 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PRIMA1 | c.130G>C p.V44L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.201); called by muse, mutect2
- PTPRM | c.2388_2406del p.E797Tfs*12 | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | called by mutect2, pindel
- RYR1 | c.11111A>C p.H3704P | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- SORBS1 | c.3418C>A p.P1140T | Missense Mutation (SNP) | VAF 95/180 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.147); called by muse, varscan2
- SYTL4 | c.647A>C p.D216A | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAGLN3 | c.224A>G p.E75G | Missense Mutation (SNP) | VAF 79/185 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TDRD15 | c.2324T>A p.L775H | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TECTA | c.3547A>T p.N1183Y | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- TET3 | c.2458A>T p.R820* | Nonsense Mutation (SNP) | VAF 75/146 reads (51%) | called by muse, mutect2, varscan2
- TLL1 | c.2947A>G p.I983V | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.009); called by muse, mutect2
- TLR4 | c.2520A>G p.*840Wext*8 (on ENST00000355622 / NM_138554.5; = p.*800Wext*8 on NM_003266.4) | Nonstop Mutation (SNP) | VAF 9/14 reads (64%) | called by muse, mutect2, varscan2
- TPM1 | c.436A>T p.I146F | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- TRPM3 | c.4598G>A p.R1533K (on ENST00000357533 / NM_001366142.2; = p.R1388K on NM_020952.6) | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- USH1G | c.121T>C p.Y41H | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ZNF181 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- ZNF23 | c.53C>G p.P18R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADRA2A | c.576C>T p.G192= | Silent (SNP) | VAF 86/156 reads (55%) | catalogued as COSV54527868; called by muse, mutect2, varscan2
- APCDD1 | c.144G>A p.K48= | Silent (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- ATP10A | c.75C>A p.R25= | Silent (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2
- CCND1 | c.129C>T p.S43= | Silent (SNP) | VAF 93/143 reads (65%) | catalogued as rs1395410503; called by muse, mutect2, varscan2
- DIP2C | c.2730C>T p.C910= | Silent (SNP) | VAF 14/31 reads (45%) | called by muse, mutect2, varscan2
- EMCN | c.597G>A p.L199= | Silent (SNP) | VAF 15/181 reads (8%) | catalogued as COSV56466103; called by muse, mutect2
- ESRRB | c.543C>A p.G181= | Silent (SNP) | VAF 52/124 reads (42%) | called by muse, mutect2, varscan2
- GDF10 | c.861C>T p.R287= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs1292525086; called by muse, mutect2, varscan2
- IGHV2-70D | c.144C>T p.L48= | Silent (SNP) | VAF 25/26 reads (96%) | called by muse, mutect2
- MRPL4 | c.666A>G p.T222= | Silent (SNP) | VAF 57/115 reads (50%) | called by muse, mutect2, varscan2
- RECQL | c.759G>A p.L253= | Silent (SNP) | VAF 52/125 reads (42%) | called by muse, mutect2, varscan2
- SLC15A3 | c.1143G>T p.V381= | Silent (SNP) | VAF 41/81 reads (51%) | called by muse, mutect2, varscan2
- VARS2 | c.2331G>A p.P777= | Silent (SNP) | VAF 65/107 reads (61%) | catalogued as rs1187001363; called by muse, mutect2, varscan2
- WDFY3 | c.1053A>G p.K351= | Silent (SNP) | VAF 30/96 reads (31%) | called by muse, mutect2, varscan2
- ZFP36L1 | c.54C>T p.C18= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as rs543677600, COSV60543983; called by muse, mutect2, varscan2
- ABCF2 | c.*161C>G | 3'UTR (SNP) | VAF 23/30 reads (77%) | called by muse, mutect2, varscan2
- AC090616.2 | n.354A>T | RNA (SNP) | VAF 48/92 reads (52%) | called by muse, mutect2, varscan2
- ACSM1 | c.1197+101C>T | Intron (SNP) | VAF 40/64 reads (63%) | catalogued as rs1397848987; called by muse, mutect2, varscan2
- ADCYAP1 | c.*2433C>A | 3'UTR (SNP) | VAF 33/76 reads (43%) | called by muse, mutect2, varscan2
- ARHGAP26 | c.*4811A>G | 3'UTR (SNP) | VAF 34/37 reads (92%) | called by muse, mutect2, varscan2
- ARID4B | c.3449-9C>T | Intron (SNP) | VAF 70/105 reads (67%) | called by muse, mutect2, varscan2
- BAIAP2L1 | c.*810C>G | 3'UTR (SNP) | VAF 12/309 reads (4%) | called by muse, mutect2
- C10orf88B | n.338G>A | RNA (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- CAMK2D | chr4:113761280 T>G | 5'Flank (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- CD44 | c.*929T>C | 3'UTR (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- CDC20B | c.*634T>C | 3'UTR (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- CES4A | c.-62C>A | 5'UTR (SNP) | VAF 54/121 reads (45%) | called by muse, mutect2, varscan2
- CHL1 | c.*191T>G | 3'UTR (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- COL5A1 | c.*1245C>T | 3'UTR (SNP) | VAF 50/95 reads (53%) | called by muse, mutect2, varscan2
- DLAT | c.*1628A>G | 3'UTR (SNP) | VAF 185/297 reads (62%) | catalogued as rs782110826; called by muse, mutect2, varscan2
- EBF3 | c.913-35C>T | Intron (SNP) | VAF 37/82 reads (45%) | called by muse, mutect2, varscan2
- EIF2AK2 | c.*6966A>G | 3'UTR (SNP) | VAF 39/83 reads (47%) | called by muse, mutect2, varscan2
- EIF2S2 | c.-120G>A | 5'UTR (SNP) | VAF 26/108 reads (24%) | called by muse, mutect2, varscan2
- ENPP2 | c.1781-1335G>T | Intron (SNP) | VAF 5/38 reads (13%) | catalogued as rs749290162; called by muse, mutect2
- EXTL3 | c.-545C>G | 5'UTR (SNP) | VAF 23/232 reads (10%) | called by muse, mutect2
- FAM210B | c.*134C>G | 3'UTR (SNP) | VAF 49/122 reads (40%) | called by muse, mutect2, varscan2
- FBXW7 | c.501+36T>C | Intron (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- GABARAP | chr17:7242483 T>C | 5'Flank (SNP) | VAF 15/21 reads (71%) | called by muse, mutect2, varscan2
- H4C5 | c.-32T>C | 5'UTR (SNP) | VAF 133/195 reads (68%) | called by muse, mutect2, varscan2
- HGF | c.865+656dup | Intron (INS) | VAF 18/47 reads (38%) | called by mutect2, pindel, varscan2
- HR | c.2006-74G>T | Intron (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- IGF2BP1 | c.*2502C>T | 3'UTR (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- IRF4 | c.-85C>G | 5'UTR (SNP) | VAF 19/58 reads (33%) | catalogued as rs1450231210; called by muse, mutect2, varscan2
- ISX | c.-696C>T | 5'UTR (SNP) | VAF 37/73 reads (51%) | called by muse, mutect2, varscan2
- ITPKB | c.1932+27830A>T | Intron (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2
- KCNK13 | c.*354T>C | 3'UTR (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- KIF5C | c.714+910A>T | Intron (SNP) | VAF 7/158 reads (4%) | called by muse, mutect2
- KLHL29 | c.2105+1329A>G | Intron (SNP) | VAF 30/68 reads (44%) | called by muse, varscan2
- LINC00602 | n.706del | RNA (DEL) | VAF 24/34 reads (71%) | called by mutect2, pindel, varscan2
- LINC01148 | n.1120A>C | RNA (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- MEGF6 | c.*528G>T | 3'UTR (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- MMP8 | c.103-365del | Intron (DEL) | VAF 7/44 reads (16%) | called by mutect2, pindel, varscan2
- Metazoa_SRP | chr15:62247089 T>C | 5'Flank (SNP) | VAF 57/130 reads (44%) | catalogued as rs1434048791; called by muse, mutect2, varscan2
- N4BP2 | c.*61G>T | 3'UTR (SNP) | VAF 19/91 reads (21%) | called by muse, mutect2
- NAGA | c.*65C>T | 3'UTR (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- NHLRC2 | c.*3479A>C | 3'UTR (SNP) | VAF 27/61 reads (44%) | called by muse, mutect2, varscan2
- NPY2R | c.*937G>T | 3'UTR (SNP) | VAF 36/78 reads (46%) | called by muse, mutect2, varscan2
- NT5C1B | chr2:18563032 C>T | 3'Flank (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- OR6C6 | c.-3G>T | 5'UTR (SNP) | VAF 21/41 reads (51%) | called by muse, mutect2, varscan2
- OTOF | c.3864+161C>G | Intron (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
- PRELID2 | c.510+868A>T | Intron (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2, varscan2
- PRIMA1 | c.*1006C>A | 3'UTR (SNP) | VAF 27/61 reads (44%) | called by muse, mutect2, varscan2
- PSMC6 | c.*290A>C | 3'UTR (SNP) | VAF 31/58 reads (53%) | called by muse, mutect2, varscan2
- PTMA | c.-137C>T | 5'UTR (SNP) | VAF 22/64 reads (34%) | catalogued as rs1021742174; called by muse, mutect2, varscan2
- RNF214 | c.619-87A>C | Intron (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- RNF224 | c.*22G>T | 3'UTR (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
- RNF24 | c.*1960T>A | 3'UTR (SNP) | VAF 23/43 reads (53%) | called by muse, mutect2, varscan2
- RPL18 | c.198+201_198+203del | Intron (DEL) | VAF 45/87 reads (52%) | catalogued as rs576713711; called by mutect2, pindel, varscan2
- RPS6KB1 | chr17:59893079 T>A | 5'Flank (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- SH3GL3 | chr15:83447305 G>C | 5'Flank (SNP) | VAF 19/33 reads (58%) | called by muse, mutect2, varscan2
- SLC12A7 | c.1454+64A>G | Intron (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2, varscan2
- SLC7A10 | c.788+70C>A | Intron (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- SOX9 | c.*1621A>C | 3'UTR (SNP) | VAF 34/67 reads (51%) | called by muse, mutect2, varscan2
- SPOP | c.*694C>T | 3'UTR (SNP) | VAF 40/77 reads (52%) | called by muse, mutect2, varscan2
- SRSF12 | c.275-72G>T | Intron (SNP) | VAF 46/53 reads (87%) | called by muse, mutect2, varscan2
- SSNA1 | c.*407C>T | 3'UTR (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- TCL1A | c.121-300G>C | Intron (SNP) | VAF 16/42 reads (38%) | called by mutect2, varscan2
- TECRL | c.*399A>C | 3'UTR (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- TEK | c.*19C>A | 3'UTR (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2, varscan2
- TLE3 | c.-1248C>G | 5'UTR (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- TLK1 | c.*1008A>T | 3'UTR (SNP) | VAF 7/102 reads (7%) | called by muse, mutect2
- TLX2 | c.*651C>A | 3'UTR (SNP) | VAF 53/108 reads (49%) | called by muse, mutect2, varscan2
- TMEM164 | c.*4159G>A | 3'UTR (SNP) | VAF 6/51 reads (12%) | catalogued as rs1184486121; called by muse, mutect2, varscan2
- TMEM78 | n.819C>A | RNA (SNP) | VAF 27/96 reads (28%) | called by muse, mutect2, varscan2
- TRIM13 | c.*3576T>C | 3'UTR (SNP) | VAF 49/49 reads (100%) | catalogued as rs1017526016; called by muse, mutect2, varscan2
- USP31 | c.*5913T>G | 3'UTR (SNP) | VAF 28/52 reads (54%) | called by muse, mutect2, varscan2
- UTP23 | c.*803G>A | 3'UTR (SNP) | VAF 30/77 reads (39%) | called by muse, mutect2, varscan2
- VPS13A | c.*4701G>A | 3'UTR (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- VSTM4 | c.457+5404A>G | Intron (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- ZC3H12C | c.22-621A>C | Intron (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- ZNF626 | c.*146T>C | 3'UTR (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- ZNF804A | c.*199C>A | 3'UTR (SNP) | VAF 7/34 reads (21%) | catalogued as COSV56457518; called by muse, mutect2, varscan2
- ZNF830 | c.-11T>C | 5'UTR (SNP) | VAF 20/42 reads (48%) | catalogued as COSV100030940; called by muse, mutect2, varscan2
